CCDI case PBBIFL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/abdc410f-27cc-4518-9340-4e449b1edcf8

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Astroblastoma: ICD-O-3 morphology code: 9430/3; Tissue or organ of origin: Overlapping lesion of brain; Age at diagnosis: 12.7 years (4,646 days).

Biospecimens (3 samples)
- Sample 0D98OH: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0D98P0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0D98P3: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
